Gene-level copy-number profile of tumor specimen TCGA-UF-A7JJ-01A from TCGA case TCGA-UF-A7JJ, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Age at diagnosis: 69.0 years (25,201 days).
Specimen TCGA-UF-A7JJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.a5f37008-2bfe-409b-949b-d72d7f0f61a9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-UF-A7JJ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/97bcc3bb-9340-4687-b553-633752c57f46

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 7,746; copy number 2: 40,160; copy number 3: 10,172; copy number 4: 1,261; copy number 5: 421; copy number 6: 24; copy number 7: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-UF-A7JJ-01A-11D-A34I-01): tumor purity 0.24, ploidy 1.79, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:60,616,822–60,856,605, 6 genes: AC104164.2, MIR548BB, PPIAP70, AC104164.1, PPIAP71, U3.
- chr9:8,314,246–10,612,723, 1 gene (within-gene range 0–2): PTPRD.
- chr9:8,936,079–9,803,784, 4 genes: AL596451.1, RPS26P3, RN7SL5P, AL513422.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 463 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:171,783,405–179,285,707, 167 genes, copy number 5 (broad region; genes not listed).
- chr2:198,882,573–200,008,540, 15 genes, copy number 7 (within-gene range 4–7): AC020718.1, AC018717.1, RNU7-147P, SATB2, AC016746.1, SATB2-AS1, LINC01877, SEPHS1P6, FTCDNL1, AC097717.1, AC108032.1, RN7SL717P, C2orf69, TYW5, MAIP1.
- chr6:66,093,431–66,728,904, 3 genes, copy number 5: NUFIP1P1, AL450336.1, RNU7-66P.
- chr7:83,663,419–84,528,830, 3 genes, copy number 7: RAD23BP2, SEMA3A, RPL7P30.
- chr7:89,882,353–91,556,848, 24 genes, copy number 6 (within-gene range 2–6): STEAP2-AS1, AC004969.1, DPY19L2P4, STEAP1, STEAP2, CFAP69, Y_RNA, AC002064.2, AC002064.1, FAM237B, GTPBP10, AC002064.3, CLDN12, AC006153.1, CDK14, AC002456.2, AC002456.1, TVP23CP1, AC002458.1, PTP4A1P3, FZD1, AC079760.2, NIPA2P1, AC079760.1.
- chr7:98,877,933–99,050,831, 1 gene, copy number 5 (within-gene range 2–5): TRRAP.
- chr7:98,989,867–101,569,006, 146 genes, copy number 5 (broad region; genes not listed).
- chr8:46,028,804–49,907,446, 71 genes, copy number 5 (broad region; genes not listed).
- chr16:59,709,993–64,343,909, 33 genes, copy number 5: APOOP5, LINC02141, AC009094.1, AC009081.2, AC018554.1, NPAP1L, AC009081.1, GNPATP, AC009169.1, RPS27AP16, AC092125.2, CDH8, AC092125.1, RN7SKP76, AC012174.1, RNU6-21P, AC009161.2, AC009161.1, AC009110.1, AC010546.1, AC040174.1, AC040174.2, UBE2FP2, AC138305.1, RPS15AP34, AC138305.2, AC138305.3, AC018846.1, LINC02165, AC092337.1, AC093536.2, AC012322.1, AC093536.1.

Autosomal genes at a single copy (total copy number 1): 5,366. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
